Somatic mutation profile of tumor specimen MBCProject_3946_T4_WES (aliquot MBCProject_3946_T4_WES_1) from CMI case MBCProject_3946, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.7 years (18,137 days).
Specimen MBCProject_3946_T4_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Fallopian Tube; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 447faf2a-e9cf-4f30-a979-1df21d23561e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3946_SALIVA (Saliva), aliquot MBCProject_3946_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4996973e-41c0-443a-a619-ca6c9d9096f6

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2
- GRIN2D | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV54379603; called by muse, mutect2
- MROH2A | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV67680482; called by mutect2, varscan2
- DHX29 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- MYOM3 | c.1970+70_1970+74del | Intron (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
